Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A4Z3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A4Z3-01A (Primary Tumor).

Department of Cancer Pathology

Gender: F

Examination result

Clinical diagnosis (suspicion) **Melanoma of the left arm**

Material:

1) Material: skin of the left arm. Large tumor of the left arm. Method of collection: resection of the tumor

Histopathological Diagnosis:

Malignant melanoma of the skin, nodular type ulcerated. Clark V, Breslow 75 mm, MI -10 mitoses/1 mm². Cancer infiltration of the fat tissue and muscles. Moderate lymphocytic infiltration.

Immunohistochemistry: HMB45 + in few cells, MelanA-, CKAE1/3-, Ki67 50%

Macroscopic description:

Tumor: 2.2 x 1.7 x 7.5 cm ulcerated lesion with skin margin from 0.5 to 1.5 cm. Muscle infiltration.

Assistant

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-O-3
melanoma, nodular 8721/3
Site: skin, arm C44.6

hw
11/4/12

Source: NCI Genomic Data Commons file 32c9b147-be4b-497c-bedd-7b6100e31b2e (TCGA-D9-A4Z3.9B96B7FD-D3BA-42C8-A0C6-1C93C48F4BB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).